Somatic mutation profile of tumor specimen TARGET-10-PARPFF-09A (aliquot TARGET-10-PARPFF-09A-01D) from TARGET case TARGET-10-PARPFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,645 days).
Specimen TARGET-10-PARPFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1e5993c-a058-4986-a47c-6cb4a66ceec4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPFF-10A (Blood Derived Normal), aliquot TARGET-10-PARPFF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c644e44-55e3-4ad6-b9d5-0a1bf483ebb9

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 2, Silent 2, Splice Site 1, 3'Flank 1, In Frame Del 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 20/36 reads (56%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- CRLF2 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1057519743, COSV67493408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFAP126 | c.27+2T>G p.X9_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- DACH2 | c.706A>C p.T236P | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MAPK1 | c.300T>C p.D100= | Splice Region (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- MUC17 | c.3695C>T p.A1232V | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAGE5 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- UNC13C | c.851T>G p.V284G | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFP36L2 | c.616T>C p.C206R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INPPL1 | c.2058C>T p.P686= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1565392826; called by muse, mutect2, varscan2
- ITPRIPL2 | c.978G>A p.P326= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs542127813, COSV67347734; called by muse, mutect2, varscan2
- ARF6 | c.-8C>G | 5'UTR (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- BTC | c.-39A>G | 5'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- IGHV1-69D | chr14:106762091 ins A | 3'Flank (INS) | VAF 15/17 reads (88%) | called by mutect2, pindel*, varscan2*
- MAGEA12 | c.*76G>T | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
